CCDI case PBCLZN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/0d9adfac-4602-40dd-a851-1e74ca2e674d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.1 years (1,514 days).

Biospecimens (3 samples)
- Sample 0DV98O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV992: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DV99P: Tissue type: Tumor; Specimen type: Solid Tissue.
